TCGA case TCGA-CA-6718 — Colon Adenocarcinoma (TCGA-COAD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Colon; Tissue source site: ILSBio. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/df5ab6cc-6f68-4b6b-95e2-954c6b57ba9c

Demographics
Sex at birth: male; Race: asian; Ethnicity: not hispanic or latino; Country of residence at enrollment: Vietnam; Age at index: 46 years; Vital status: Dead; Days to death: 306 days.

Diagnoses (2)
1. Adenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8140/3; ICD-10 code: C18.9; Tissue or organ of origin: Colon, NOS; Site of resection or biopsy: Ascending colon; Classification of tumor: primary; Age at diagnosis: 46.8 years (17,109 days); Year of diagnosis: 2010; AJCC staging edition: 6th; AJCC pathologic T: T3; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIA; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: RX; Days to last follow up: 306 days.
   Pathology details: Consistent pathology review: Yes.
   Treatment given: Treatment type: Radiation, External Beam; Days to treatment start: 207 days; Days to treatment end: 238 days; Treatment dose: 30 Gy; Treatment outcome: Progressive Disease; Number of fractions: 10; Treatment anatomic sites: Distant Site.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS.
2. Diagnosis record without a diagnosis name: Tumor of origin: diagnosis 1 of this record; Age at diagnosis: 47.4 years (17,316 days); Days to diagnosis: 207 days; Prior treatment: Yes.
   Treatment given: Treatment type: Radiation Therapy, NOS.
   Recorded as not given: Pharmaceutical Therapy, NOS; Surgery, NOS.

Follow-up (3 entries)
- Days to follow up: 3 days; Disease response: Tumor Free.
- Day 207 (post initial treatment): Progression or recurrence: Yes; Days to recurrence: 207 days.
- Days to follow up: 306 days; Disease response: With Tumor.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 63 kg; Height: 168 cm; BMI: 22.3.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-CA-6718-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Longest dimension: 1.7; Intermediate dimension: 1.4; Shortest dimension: 0.5.
  Slide TCGA-CA-6718-01A-01-TS1: Section location: Top; Percent tumor cells: 67; Percent tumor nuclei: 75; Percent normal cells: 8; Percent necrosis: 0; Percent stromal cells: 25.
  Slide TCGA-CA-6718-01A-01-BS1: Section location: Bottom; Percent tumor cells: 73; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 12; Percent stromal cells: 15.
- Sample TCGA-CA-6718-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-CA-6718-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: History neoadjuvant treatment: No; Prospective collection: Yes; Retrospective collection: No; Tumor status: Tumor free; Lymph nodes examined: No.
- Radiation treatment: Treatment best response: Radiographic Progressive Disease.
- Follow-up form: Lost to follow-up: No; Treatment outcome first course: Complete Remission/Response; Tumor status: With tumor; New tumor event diagnosis indicator: Yes.
- Follow-up form, New tumor event: New tumor event surgery: No; New tumor event radiation treatment: Yes; New tumor event pharmaceutical treatment: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 306 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 306 days; disease-free interval: event (new tumor event after initially disease-free), 207 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 207 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-CA-6718-01A-11D-1834-01): tumor purity 0.48, ploidy 2.09, whole-genome doublings 0.
